Somatic mutation profile of tumor specimen HCM-WCMC-0671-C18-01A (aliquot HCM-WCMC-0671-C18-01A-15D-A85C-36) from HCMI case HCM-WCMC-0671-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 47.4 years (17,322 days).
Specimen HCM-WCMC-0671-C18-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcb04945-3043-4db1-8f4e-5c873775db2d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0671-C18-10A (Blood Derived Normal), aliquot HCM-WCMC-0671-C18-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7d45e68-e2ba-4ac9-8e31-70ac16d19327

The open-access MAF lists 98 somatic variants for this specimen: 63 protein-altering or splice-affecting, 32 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 32, 3'UTR 1, Nonsense Mutation 1, 5'Flank 1, RNA 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 310/691 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.5401G>A p.E1801K | Missense Mutation (SNP) | VAF 293/814 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs397516248, CM1410901, COSV100806734; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 142/380 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- YY1AP1 | c.2125G>T p.E709* (on ENST00000295566 / NM_139118.2; = p.E652* on NM_018253.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 89/340 reads (26%) | catalogued as rs1057519598, COSV55120465; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRG7 | c.1645G>T p.A549S | Missense Mutation (SNP) | VAF 111/355 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.179); catalogued as COSV56295981; called by muse, mutect2, varscan2
- AP002748.5 | c.1435C>T p.R479W | Missense Mutation (SNP) | VAF 58/328 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1370913745; called by muse, varscan2
- ARHGEF19 | c.316C>A p.P106T | Missense Mutation (SNP) | VAF 106/545 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.262); catalogued as COSV54615416, COSV54617495; called by muse, mutect2, varscan2
- CELSR3 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 88/522 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV99375237; called by muse, varscan2
- CFTR | c.2327C>T p.S776L | Missense Mutation (SNP) | VAF 113/424 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs397508365, CM972954; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A3 | c.3782C>T p.T1261M | Missense Mutation (SNP) | VAF 60/432 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as rs772890229; called by muse, mutect2, varscan2
- CSRNP3 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 18/520 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1353543644, COSV58775303; called by muse, mutect2
- DKK2 | c.137C>T p.T46M | Missense Mutation (SNP) | VAF 203/637 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.288); catalogued as rs1366887020, COSV99568057; called by muse, mutect2, varscan2
- DMD | c.8852G>A p.R2951H | Missense Mutation (SNP) | VAF 66/442 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs72466567, COSV58933390; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- ERCC2 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 106/650 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs759930858, COSV55540243; called by muse, varscan2
- FKBP7 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 69/249 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs778701740; called by muse, mutect2, varscan2
- GALNT12 | c.1156G>A p.V386I | Missense Mutation (SNP) | VAF 156/570 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV66663311; called by muse, mutect2, varscan2
- GDPD2 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 112/791 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs777943165; called by muse, mutect2, varscan2
- GPR158 | c.2876A>C p.Q959P | Missense Mutation (SNP) | VAF 68/363 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs775893038; called by mutect2, varscan2
- HS3ST3A1 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 96/928 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as rs750522076, COSV52372487; called by muse, varscan2
- IFT140 | c.2323G>A p.A775T | Missense Mutation (SNP) | VAF 77/558 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs771255082; called by muse, varscan2
- ITGA8 | c.172G>C p.G58R | Missense Mutation (SNP) | VAF 90/480 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100958992; called by muse, varscan2
- KDM4D | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 80/571 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.617); catalogued as rs781785317; called by muse, mutect2, varscan2
- KIAA1549L | c.5267C>T p.S1756L (on ENST00000321505; = p.S2053L on NM_012194.3) | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1205996425, COSV58584314; called by muse, mutect2, varscan2
- KLF5 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 233/521 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66614378, COSV66615313; called by muse, mutect2, varscan2
- KLHL38 | c.1577C>T p.T526M | Missense Mutation (SNP) | VAF 310/968 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs373548260; called by muse, varscan2
- MYO3A | c.4163G>T p.R1388I | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV56329554; called by muse, mutect2, varscan2
- NEUROD1 | c.401C>T p.T134M | Missense Mutation (SNP) | VAF 96/575 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765540175, COSV54548386; called by muse, mutect2, varscan2
- NIPBL | c.2495G>A p.R832Q | Missense Mutation (SNP) | VAF 99/361 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.087); catalogued as rs150498581, COSV99241547; called by muse, mutect2, varscan2
- NLRP6 | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 151/559 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs777994754, COSV56459160, COSV56459330; called by muse, varscan2
- OR2W3 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 82/485 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.806); catalogued as rs759398397, COSV64455968; called by muse, varscan2
- OR9I1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 49/344 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as rs145179217; called by muse, mutect2, varscan2
- PPP1R2C | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 106/457 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs779855030, COSV65363978; called by muse, varscan2
- PRELP | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 172/572 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs554590706, COSV58116609; called by muse, mutect2, varscan2
- PTGER3 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 198/636 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.328); catalogued as COSV100138502, COSV60695422; called by muse, varscan2
- RAB11FIP5 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 68/430 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs372149039, COSV50248399; called by muse, varscan2
- RBM12 | c.1350T>A p.F450L | Missense Mutation (SNP) | VAF 286/600 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV58290226; called by muse, varscan2
- RP1L1 | c.4529C>T p.A1510V | Missense Mutation (SNP) | VAF 56/432 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs373409421; called by muse, varscan2
- SETD3 | c.576_578del p.D192del | In Frame Del (DEL) | VAF 106/326 reads (33%) | catalogued as rs748875088; called by mutect2, varscan2
- SLC25A53 | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 185/748 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782336534; called by muse, varscan2
- TUBA3C | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 235/646 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as rs1333388009, COSV104433929; called by muse, varscan2
- UBQLN3 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 88/474 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs1284294682, COSV100294044; called by muse, mutect2, varscan2
- UGT2B10 | c.612G>T p.M204I | Missense Mutation (SNP) | VAF 57/311 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV55322200; called by muse, varscan2
- ZBTB33 | c.968G>T p.G323V | Missense Mutation (SNP) | VAF 114/666 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.193); catalogued as COSV58532966; called by muse, mutect2, varscan2
- ZFHX4 | c.9230C>T p.T3077M | Missense Mutation (SNP) | VAF 232/649 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as rs377249680; called by muse, mutect2, varscan2
- AHNAK2 | c.11822C>T p.P3941L | Missense Mutation (SNP) | VAF 118/959 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.577); called by muse, mutect2
- APC | c.4188del p.F1396Lfs*19 | Frame Shift Del (DEL) | VAF 44/234 reads (19%) | called by mutect2, varscan2
- ARSG | c.103A>G p.K35E | Missense Mutation (SNP) | VAF 80/385 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ATP6V1FNB | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 89/655 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- CAPS2 | c.345A>T p.K115N | Missense Mutation (SNP) | VAF 60/197 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CEP170 | c.1661C>A p.A554E | Missense Mutation (SNP) | VAF 68/472 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.055); called by mutect2, varscan2
- FBF1 | c.1165C>A p.L389M (on ENST00000586717; = p.L403M on NM_001319193.1) | Missense Mutation (SNP) | VAF 88/385 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- FBN2 | c.3677C>T p.S1226F | Missense Mutation (SNP) | VAF 61/301 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HECTD3 | c.310G>T p.V104L | Missense Mutation (SNP) | VAF 193/528 reads (37%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IRX1 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 172/590 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, varscan2
- MINAR1 | c.1047A>T p.Q349H | Missense Mutation (SNP) | VAF 156/464 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MXRA5 | c.4427C>A p.T1476N | Missense Mutation (SNP) | VAF 76/384 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0); called by mutect2, varscan2
- PCDH10 | c.2683G>T p.V895F | Missense Mutation (SNP) | VAF 93/342 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- POMT2 | c.1388T>G p.F463C | Missense Mutation (SNP) | VAF 75/464 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.176); called by muse, mutect2
- SLC35B1 | c.707C>T p.T236I (on ENST00000649906; = p.T199I on NM_005827.4) | Missense Mutation (SNP) | VAF 52/289 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- SOX3 | c.138G>T p.E46D | Missense Mutation (SNP) | VAF 190/831 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by muse, varscan2
- SPOCD1 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 64/424 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.063); called by muse, varscan2
- TRIM63 | c.103G>T p.V35F | Missense Mutation (SNP) | VAF 144/445 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- USH2A | c.10037C>A p.A3346E | Missense Mutation (SNP) | VAF 172/487 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- AC011448.1 | c.555C>T p.N185= | Silent (SNP) | VAF 123/437 reads (28%) | catalogued as rs369545105; called by muse, mutect2, varscan2
- ADAMTS10 | c.372C>T p.Y124= | Silent (SNP) | VAF 148/694 reads (21%) | catalogued as rs138572540; called by muse, mutect2, varscan2
- ADCY8 | c.75C>T p.G25= | Silent (SNP) | VAF 210/774 reads (27%) | called by muse, mutect2, varscan2
- ARRB1 | c.1026C>T p.D342= | Silent (SNP) | VAF 198/536 reads (37%) | catalogued as rs150290364; called by muse, mutect2, varscan2
- BNC2 | c.2673G>C p.L891= | Silent (SNP) | VAF 34/376 reads (9%) | called by muse, mutect2
- CACHD1 | c.2739G>A p.T913= | Silent (SNP) | VAF 83/231 reads (36%) | catalogued as rs1202602620, COSV51553609; called by muse, mutect2, varscan2
- CADPS | c.2148C>T p.C716= | Silent (SNP) | VAF 48/291 reads (16%) | catalogued as rs368353277; called by muse, varscan2
- CDKL5 | c.2670G>T p.R890= | Silent (SNP) | VAF 96/537 reads (18%) | called by muse, mutect2, varscan2
- DAAM1 | c.1386A>G p.L462= | Silent (SNP) | VAF 31/294 reads (11%) | catalogued as rs1214958284, COSV100658423; called by muse, varscan2
- DCLK1 | c.213G>T p.G71= | Silent (SNP) | VAF 73/555 reads (13%) | called by mutect2, varscan2
- FAM126A | c.1335C>T p.T445= | Silent (SNP) | VAF 131/415 reads (32%) | catalogued as rs776382371; called by muse, varscan2
- FAM189A2 | c.1263G>A p.A421= | Silent (SNP) | VAF 122/820 reads (15%) | catalogued as rs772335309; called by muse, varscan2
- FRMD6 | c.1635C>T p.L545= (on ENST00000344768 / NM_001267046.2; = p.L537= on NM_152330.4) | Silent (SNP) | VAF 100/413 reads (24%) | catalogued as rs1179548355, COSV100656348; called by muse, mutect2, varscan2
- FZD10 | c.1179G>A p.A393= | Silent (SNP) | VAF 102/571 reads (18%) | catalogued as rs543088043; called by muse, varscan2
- GABBR1 | c.2838C>T p.P946= | Silent (SNP) | VAF 38/1177 reads (3%) | catalogued as rs1445845110; called by muse, mutect2
- MKNK2 | c.93C>T p.P31= | Silent (SNP) | VAF 89/580 reads (15%) | catalogued as rs919109829; called by muse, mutect2, varscan2
- MTOR | c.1023C>T p.G341= | Silent (SNP) | VAF 87/471 reads (18%) | called by muse, mutect2, varscan2
- NFATC2 | c.2199G>A p.T733= | Silent (SNP) | VAF 489/1033 reads (47%) | catalogued as rs558006319, COSV65354617; called by muse, mutect2, varscan2
- NINL | c.2313C>T p.R771= | Silent (SNP) | VAF 498/1060 reads (47%) | catalogued as rs1292476724; called by muse, varscan2
- OR51A4 | c.264G>C p.L88= | Silent (SNP) | VAF 52/378 reads (14%) | catalogued as COSV66749337; called by muse, mutect2, varscan2
- OR8H2 | c.72C>A p.I24= | Silent (SNP) | VAF 100/317 reads (32%) | catalogued as COSV57943031; called by muse, mutect2, varscan2
- PDZK1IP1 | c.201C>T p.T67= | Silent (SNP) | VAF 55/376 reads (15%) | catalogued as rs138001097; called by muse, varscan2
- PGAP4 | c.549G>A p.S183= | Silent (SNP) | VAF 126/510 reads (25%) | catalogued as rs535197432, COSV66388136; called by muse, varscan2
- PPP2R2A | c.627C>T p.D209= | Silent (SNP) | VAF 14/188 reads (7%) | called by muse, mutect2
- PRSS35 | c.1029G>A p.S343= | Silent (SNP) | VAF 65/438 reads (15%) | catalogued as rs757228644, COSV63800234; called by muse, varscan2
- RSPH6A | c.147C>T p.D49= | Silent (SNP) | VAF 194/582 reads (33%) | catalogued as rs1207903523; called by muse, varscan2
- SCTR | c.588C>T p.D196= | Silent (SNP) | VAF 154/486 reads (32%) | catalogued as rs746911205, COSV50026827; called by muse, mutect2, varscan2
- SLC1A2 | c.624C>T p.T208= | Silent (SNP) | VAF 72/494 reads (15%) | called by muse, mutect2, varscan2
- SLC9B2 | c.1288T>C p.L430= | Silent (SNP) | VAF 96/368 reads (26%) | called by muse, mutect2, varscan2
- TMEM132D | c.1878C>T p.G626= | Silent (SNP) | VAF 66/372 reads (18%) | catalogued as rs140308183; called by muse, varscan2
- TTN | c.71559C>T p.D23853= (on ENST00000591111; = p.D16429= on NM_003319.4) | Silent (SNP) | VAF 154/470 reads (33%) | catalogued as rs370908118; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- VIPAS39 | c.78C>T p.D26= | Silent (SNP) | VAF 121/357 reads (34%) | catalogued as rs112217896; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130915738 G>A | 5'Flank (SNP) | VAF 121/590 reads (21%) | catalogued as rs1025906166; called by muse, mutect2, varscan2
- CAPZB | c.*18C>T | 3'UTR (SNP) | VAF 84/448 reads (19%) | called by muse, mutect2, varscan2
- MYOSLID | n.158G>A | RNA (SNP) | VAF 149/496 reads (30%) | catalogued as rs144141552; called by muse, mutect2, varscan2
